Somatic mutation profile of tumor specimen TCGA-DK-A3IL-01A (aliquot TCGA-DK-A3IL-01A-11D-A20D-08) from TCGA case TCGA-DK-A3IL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.5 years (29,047 days).
Specimen TCGA-DK-A3IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9126a71-991b-4084-a43f-a15c89d506ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IL-10A (Blood Derived Normal), aliquot TCGA-DK-A3IL-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38e5ce67-56ac-4cac-9c7d-2bb7e9f3cb9b

The open-access MAF lists 206 somatic variants for this specimen: 161 protein-altering or splice-affecting, 37 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 37, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, Intron 3, RNA 3, Splice Site 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.684T>A p.H228Q | Missense Mutation (SNP) | VAF 62/198 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57253302; called by muse, mutect2, varscan2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 40/63 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs113993967, CM020797, COSV53196709, COSV53203439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4661G>T p.G1554V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760494159, CM136226, COSV56850483; called by muse, mutect2, varscan2
- ADAM32 | c.1936C>A p.P646T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV101165345; called by muse, mutect2, varscan2
- ANK2 | c.8444A>G p.Q2815R | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV52161070; called by muse, mutect2, varscan2
- ATMIN | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs754899712, COSV55146059; called by muse, mutect2, varscan2
- ATP1A2 | c.3001G>A p.V1001I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753885192, COSV63403730; called by muse, mutect2, varscan2
- ATP5MC1 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV63506134; called by muse, mutect2, varscan2
- AUH | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV57863246; called by muse, mutect2, varscan2
- BANK1 | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); catalogued as COSV59842745; called by muse, mutect2, varscan2
- BANP | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated, low confidence (0.57); PolyPhen probably damaging (0.942); catalogued as COSV53737641; called by muse, mutect2, varscan2
- C10orf88 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64403961; called by muse, mutect2, varscan2
- C2CD3 | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV58093017; called by muse, mutect2, varscan2
- CAPN5 | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53687858, COSV53690727; called by muse, mutect2, varscan2
- CCN6 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57889337; called by muse, mutect2, varscan2
- CCNQ | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52344345; called by muse, mutect2, varscan2
- CCR1 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56122210; called by muse, mutect2, varscan2
- CDC5L | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101014906, COSV65175715; called by muse, mutect2, varscan2
- CDK8 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101037639, COSV67420711; called by muse, mutect2, varscan2
- CEP290 | c.3404G>T p.R1135M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58351736; called by muse, mutect2, varscan2
- CFAP65 | c.385C>T p.H129Y (on ENST00000341552 / NM_194302.4; = p.H64Y on NM_152389.4) | Missense Mutation (SNP) | VAF 76/97 reads (78%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV55390312; called by muse, mutect2, varscan2
- CGB5 | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.25); catalogued as COSV100031878; called by muse, varscan2
- CNTLN | c.3593G>T p.R1198I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52078616; called by muse, mutect2, varscan2
- COL4A5 | c.4945C>A p.L1649M | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60361529; called by muse, mutect2, varscan2
- CPNE2 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); catalogued as rs1275789908, COSV51962385; called by muse, mutect2, varscan2
- DDI2 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60779735, COSV60781753; called by muse, mutect2, varscan2
- DGKI | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55950237; called by muse, mutect2, varscan2
- DHX34 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs141177029; called by muse, mutect2, varscan2
- DIDO1 | c.4236G>C p.R1412S | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56622241; called by muse, mutect2, varscan2
- DNAH1 | c.7360G>T p.D2454Y | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV70229023; called by muse, mutect2, varscan2
- DNAJB13 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 84/109 reads (77%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV60269515; called by muse, mutect2, varscan2
- EHBP1 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50420285; called by muse, mutect2
- EPHB1 | c.2746G>A p.V916M | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753895808, COSV67659919, COSV67664940, COSV67675335; called by muse, mutect2, varscan2
- FMNL2 | c.1727G>C p.G576A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as rs1215505814, COSV56495062; called by muse, mutect2, varscan2
- FMO2 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 102/187 reads (55%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.599); catalogued as COSV52947722, COSV52950860; called by muse, mutect2, varscan2
- FMO3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs200985454, COSV63006775; called by muse, mutect2, varscan2
- GABBR1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.286); catalogued as rs757008467, COSV63540730; called by muse, mutect2, varscan2
- GABRG2 | c.911T>C p.V304A (on ENST00000361925 / NM_001375343.1; = p.V264A on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.79); catalogued as COSV62718015; called by muse, mutect2, varscan2
- GPC5 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV65598806; called by muse, mutect2, varscan2
- GPRC6A | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); catalogued as rs200835880, COSV59953026; called by muse, mutect2, varscan2
- GPSM2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51442486; called by muse, mutect2, varscan2
- GRHL3 | c.1201G>T p.D401Y (on ENST00000350501 / NM_198174.3; = p.D406Y on NM_021180.3) | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52566584; called by muse, mutect2, varscan2
- GRK5 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64866406; called by muse, mutect2, varscan2
- GTSF1 | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59938681; called by muse, mutect2, varscan2
- GUCY1A1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.633); catalogued as COSV56650583, COSV56651597; called by muse, mutect2, varscan2
- H6PD | c.2189G>T p.S730I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV66231012; called by muse, mutect2, varscan2
- HDAC6 | c.3344A>G p.H1115R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57806786; called by muse, mutect2, varscan2
- HINFP | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1461847163, COSV63432012; called by muse, mutect2, varscan2
- IFT172 | c.4075G>T p.D1359Y | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53133628; called by muse, mutect2, varscan2
- IGHV3-15 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.035); catalogued as rs547870950; called by mutect2, varscan2
- IL2RB | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as COSV53426280; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ITGAM | c.2130G>T p.Q710H (on ENST00000648685 / NM_001145808.2; = p.Q709H on NM_000632.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV54937105; called by muse, mutect2, varscan2
- KCNH3 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV57790790; called by muse, mutect2, varscan2
- KCNN4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV53455494; called by muse, mutect2, varscan2
- KDM3B | c.1094_1098del p.R365Tfs*6 | Frame Shift Del (DEL) | VAF 99/236 reads (42%) | catalogued as COSV58690736; called by mutect2, pindel, varscan2
- KLHL13 | c.241-1G>T p.X81_splice | Splice Site (SNP) | VAF 51/109 reads (47%) | catalogued as COSV53247520; called by muse, mutect2, varscan2
- LILRB1 | c.1877C>T p.A626V (on ENST00000427581; = p.A575V on NM_006669.6) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs1328117804, COSV61117923; called by muse, mutect2, varscan2
- LMX1A | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as rs776905403, COSV54225521; called by muse, mutect2, varscan2
- LRIT1 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV64512377, COSV64512656; called by muse, mutect2, varscan2
- LTF | c.1631A>G p.Y544C | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51607993; called by muse, mutect2, varscan2
- MACF1 | c.10068C>A p.F3356L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV57120979; called by muse, mutect2, varscan2
- MALSU1 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV51684545; called by muse, mutect2, varscan2
- MAPK11 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57997080; called by muse, mutect2, varscan2
- MDN1 | c.16036G>C p.D5346H | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65521563; called by muse, varscan2
- MED26 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 52/58 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs577661611, COSV54660235; called by muse, mutect2, varscan2
- MFSD11 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100333921, COSV60623788; called by muse, mutect2, varscan2
- MLLT1 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 104/143 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV53130614; called by muse, mutect2, varscan2
- MSGN1 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV55262894; called by muse, mutect2, varscan2
- MUC17 | c.4085T>C p.V1362A | Missense Mutation (SNP) | VAF 215/525 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs751762337, COSV60288444; called by muse, mutect2
- MYO18B | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59134360; called by muse, mutect2, varscan2
- MYO18B | c.2671C>A p.L891I | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.345); catalogued as COSV59134367; called by muse, mutect2, varscan2
- MYO3A | c.4142C>T p.T1381I | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV56330785; called by muse, mutect2, varscan2
- MYT1 | c.3136A>G p.N1046D | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60505768; called by muse, mutect2, varscan2
- N4BP2L2 | c.1435A>G p.N479D | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227188; called by muse, mutect2, varscan2
- NDC80 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs766519914, COSV55247894; called by muse, mutect2, varscan2
- NELL1 | c.750G>C p.M250I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV100119195, COSV54265162; called by muse, mutect2, varscan2
- NIM1K | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.306); catalogued as rs761270527, COSV58139934, COSV58141733; called by muse, mutect2, varscan2
- NRXN2 | c.5093C>T p.T1698M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs779270035, COSV55449070; called by muse, mutect2, varscan2
- NRXN2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs536698209, COSV55453255; called by muse, mutect2, varscan2
- NSD2 | c.1574A>G p.K525R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV56390747; called by muse, mutect2, varscan2
- OGT | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65480764; called by muse, mutect2, varscan2
- OR10T2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); catalogued as COSV57781317; called by muse, mutect2, varscan2
- OR4C15 | c.487G>T p.V163L (on ENST00000314644; = p.V109L on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV58951458, COSV58952834; called by muse, mutect2, varscan2
- PCDH1 | c.3346A>G p.M1116V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as COSV54613954; called by muse, mutect2, varscan2
- PCDHA11 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56501316; called by muse, mutect2, varscan2
- PDE9A | c.1704C>A p.D568E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52325951; called by muse, mutect2, varscan2
- PDZD2 | c.2277C>G p.S759R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56858332; called by muse, mutect2, varscan2
- PJA1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV64053062; called by muse, mutect2, varscan2
- PLAT | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.079); catalogued as COSV54275618; called by muse, mutect2, varscan2
- PLD3 | c.1126G>C p.A376P | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52521006; called by muse, mutect2, varscan2
- PLEKHG2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs1185854708, COSV52683210; called by muse, mutect2, varscan2
- PMEL | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as rs1302490974, COSV62428814; called by muse, mutect2, varscan2
- PODN | c.590A>G p.N197S (on ENST00000395871; = p.N149S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs367579309; called by muse, mutect2, varscan2
- PRKAA2 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64803732; called by muse, mutect2, varscan2
- PRPF6 | c.2725G>T p.G909W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53870658; called by muse, varscan2
- PTPRF | c.5359G>T p.A1787S | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63443940, COSV63444954; called by muse, mutect2, varscan2
- RALGAPA2 | c.1071G>T p.Q357H | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.423); catalogued as COSV52497539, COSV99174949; called by muse, mutect2, varscan2
- RBBP6 | c.4594A>G p.S1532G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV60505130; called by muse, mutect2, varscan2
- RBM14 | c.64T>A p.F22I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV59558918; called by muse, mutect2, varscan2
- RGS7BP | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs202031234, COSV100470469, COSV61834860; called by muse, mutect2, varscan2
- RHOB | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RNF152 | c.374G>C p.S125T | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV57185450; called by muse, mutect2, varscan2
- RP1L1 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.353); catalogued as COSV66754958; called by muse, mutect2, varscan2
- SAC3D1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV57246926; called by muse, mutect2, varscan2
- SAMD10 | c.194G>C p.W65S | Missense Mutation (SNP) | VAF 116/209 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV53870639; called by muse, mutect2, varscan2
- SCG2 | c.1606G>C p.D536H | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV59539990; called by muse, mutect2, varscan2
- SHC4 | c.1867C>G p.P623A | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV60112289; called by muse, mutect2, varscan2
- SHROOM2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV66606579; called by muse, mutect2, varscan2
- SLC29A1 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57578426; called by muse, mutect2, varscan2
- SLC35G3 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52011160; called by muse, mutect2, varscan2
- SNX32 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV57449502; called by muse, mutect2, varscan2
- SRRM4 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as rs376151397, COSV57416220; called by muse, mutect2, varscan2
- SSH2 | c.2890C>A p.H964N | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.006); catalogued as COSV52172306, COSV99282526; called by muse, mutect2, varscan2
- STAB1 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV58736195; called by muse, mutect2, varscan2
- STX5 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 266/442 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53679400; called by muse, mutect2, varscan2
- SYNE1 | c.25057G>A p.E8353K (on ENST00000367255 / NM_182961.4; = p.E8305K on NM_033071.3) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1472181808, COSV54980169; called by muse, mutect2, varscan2
- SYPL1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as COSV50578883; called by muse, mutect2, varscan2
- SYT16 | c.1261G>C p.A421P | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV70856565; called by muse, mutect2, varscan2
- TBC1D8 | c.3398C>T p.S1133F | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV51821596; called by muse, varscan2
- TBCCD1 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as COSV58662184, COSV58662210; called by muse, mutect2, varscan2
- TCTN2 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV57632986; called by muse, mutect2, varscan2
- TEF | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 126/238 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV56747847; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1192412909, COSV51512137, COSV99304921; called by mutect2, varscan2
- THOC2 | c.4225C>T p.R1409C | Missense Mutation (SNP) | VAF 169/313 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773323309, COSV55541985, COSV55545868; called by muse, mutect2, varscan2
- TMEM132B | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100171416, COSV54753724; called by muse, mutect2, varscan2
- TMEM245 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV65822686; called by muse, mutect2, varscan2
- TNFRSF10D | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs750153116, COSV57035734; called by muse, mutect2, varscan2
- TOGARAM1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61888156; called by muse, mutect2, varscan2
- TPO | c.1422C>A p.D474E | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV61101796; called by muse, mutect2, varscan2
- TTN | c.2516T>C p.I839T (on ENST00000591111; = p.I793T on NM_003319.4) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | PolyPhen possibly damaging (0.599); catalogued as COSV60060168; called by muse, mutect2, varscan2
- UNC79 | c.1153G>C p.V385L (on ENST00000393151 / NM_001346218.2; = p.V208L on NM_020818.5) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV56387825; called by muse, mutect2, varscan2
- USP24 | c.5992G>T p.D1998Y | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53767556; called by muse, mutect2, varscan2
- WDR6 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV58244991; called by muse, mutect2, varscan2
- WFDC3 | c.32C>A p.A11E | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54785100; called by muse, mutect2, varscan2
- ZFHX4 | c.4881G>T p.E1627D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV50796506; called by muse, mutect2, varscan2
- ZNF205 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs763302642, COSV54620939, COSV99530545; called by muse, mutect2, varscan2
- ZNF302 | c.1135C>G p.L379V (on ENST00000627982; = p.L300V on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71063555; called by muse, mutect2, varscan2
- ZNF324B | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.996); catalogued as COSV60741795; called by muse, mutect2, varscan2
- ZNF331 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV53476824; called by muse, mutect2, varscan2
- ZNF420 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV58494068; called by muse, mutect2, varscan2
- ZNF536 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV62821636, COSV62837321; called by muse, mutect2, varscan2
- ZNF780A | c.1376A>G p.Q459R | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.182); catalogued as COSV61815412; called by muse, mutect2, varscan2
- ZNF831 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV64040199; called by muse, mutect2
- CX3CL1 | c.955_961del p.M319Pfs*108 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- GDF6 | c.1048dup p.S350Ffs*89 | Frame Shift Ins (INS) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- GRHL3 | c.407dup p.A138Gfs*32 (on ENST00000350501 / NM_198174.3; = p.A143Gfs*32 on NM_021180.3) | Frame Shift Ins (INS) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- IFI16 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- IGBP1P2 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 177/371 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LIPE | c.1973A>T p.Q658L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NKG7 | c.389_391del p.S130del | In Frame Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1185_1191del p.I396Kfs*41 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | called by mutect2, pindel, varscan2
- PCDHGA12 | c.168_169dup p.R57Pfs*22 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, pindel
- PLXNB3 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- SFTPB | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 56/95 reads (59%) | called by muse, mutect2, varscan2
- UBXN11 | c.931C>T p.Q311* (on ENST00000374221 / NM_183008.2; = p.Q278* on NM_145345.2) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- ZNF197 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- AADAT | c.921A>G p.L307= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs745937578, COSV61787220; called by muse, mutect2, varscan2
- ACAT1 | c.477T>C p.V159= | Silent (SNP) | VAF 64/271 reads (24%) | catalogued as COSV54920994; called by muse, mutect2, varscan2
- ADPRM | c.66C>T p.V22= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV65754651; called by mutect2, varscan2
- ANKS3 | c.684G>C p.L228= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58508962; called by muse, mutect2, varscan2
- ARHGAP31 | c.1287G>A p.P429= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs759683631, COSV51792330; called by muse, mutect2, varscan2
- ATF2 | c.591A>G p.V197= | Silent (SNP) | VAF 150/263 reads (57%) | catalogued as rs1358219991, COSV51369338; called by muse, mutect2, varscan2
- CCDC28A | c.84C>A p.A28= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as COSV60424993; called by muse, mutect2, varscan2
- CDH13 | c.55C>T p.L19= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs1277791254, COSV51819626; called by muse, mutect2, varscan2
- CFAP47 | c.2352G>A p.Q784= | Silent (SNP) | VAF 98/191 reads (51%) | catalogued as COSV52884587; called by muse, mutect2, varscan2
- CHD3 | c.2328C>T p.Y776= | Silent (SNP) | VAF 63/85 reads (74%) | catalogued as rs1414291457, COSV57874999; called by muse, mutect2, varscan2
- CNN1 | c.771C>A p.G257= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as rs999982184, COSV52947729; called by muse, mutect2, varscan2
- EXTL1 | c.135C>T p.G45= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV65337554; called by muse, mutect2, varscan2
- FAT1 | c.10479G>T p.P3493= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs774680240, COSV71673909; called by muse, mutect2, varscan2
- FLNC | c.312C>G p.L104= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs762302204, COSV57955813; called by muse, mutect2, varscan2
- FRMD7 | c.174G>A p.E58= | Silent (SNP) | VAF 57/199 reads (29%) | catalogued as COSV53746151; called by muse, mutect2, varscan2
- FSHR | c.2052C>T p.Y684= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV58623625; called by muse, mutect2, varscan2
- GATA4 | c.1257G>A p.Q419= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs1264204434, COSV58733774, COSV58734086; called by muse, varscan2
- GRIK3 | c.2391G>A p.E797= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV66139893; called by muse, mutect2, varscan2
- IL1RAP | c.1533G>A p.V511= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV50761594; called by muse, mutect2, varscan2
- KDM5B | c.3006A>G p.A1002= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs376018304; called by muse, mutect2, varscan2
- KLHL1 | c.1752C>T p.A584= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV64772416; called by muse, mutect2, varscan2
- LRRC37B | c.258G>C p.L86= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV58952499; called by muse, mutect2, varscan2
- LRRC52 | c.753C>T p.I251= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs772312807, COSV54232158; called by muse, mutect2, varscan2
- LRRK1 | c.4191T>A p.L1397= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV52611549; called by muse, mutect2, varscan2
- MACC1 | c.525G>A p.R175= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV60542938; called by muse, mutect2, varscan2
- MDM4 | c.594G>A p.L198= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV65795619; called by muse, mutect2, varscan2
- MYBPC2 | c.2358C>G p.A786= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV63095535; called by muse, mutect2, varscan2
- NOA1 | c.1035C>A p.G345= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV51736997; called by muse, mutect2, varscan2
- OR11H1 | c.639T>G p.G213= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV53271903; called by muse, mutect2, varscan2
- PIDD1 | c.2184G>A p.V728= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs981915953, COSV57193281; called by muse, mutect2, varscan2
- PRR5L | c.156C>A p.A52= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1424821376; called by muse, mutect2
- PSMD10 | c.201T>C p.N67= | Silent (SNP) | VAF 266/503 reads (53%) | catalogued as COSV54264137; called by muse, mutect2, varscan2
- PSTPIP1 | c.717C>T p.S239= | Silent (SNP) | VAF 79/207 reads (38%) | catalogued as COSV51199913; called by muse, mutect2, varscan2
- SGSM3 | c.1875C>T p.V625= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs140197200, COSV50652227; called by muse, mutect2, varscan2
- TSPAN10 | c.174C>T p.L58= (on ENST00000574882 / NM_001290212.1; = p.L20= on NM_031945.4) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV60773028; called by muse, mutect2, varscan2
- ZBTB45 | c.555A>G p.P185= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV63524060; called by muse, mutect2, varscan2
- ZNF25 | c.765G>A p.E255= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as COSV56922566; called by muse, mutect2, varscan2
- ABLIM2 | c.1168+1829G>T | Intron (SNP) | VAF 15/58 reads (26%) | catalogued as COSV56404482; called by muse, mutect2, varscan2
- AC024940.1 | n.4983G>A | RNA (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- BAGE2 | n.295G>T | RNA (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- BIRC8 | n.1491G>C | RNA (SNP) | VAF 36/116 reads (31%) | catalogued as rs1385470294, COSV100136482, COSV58842697; called by muse, mutect2, varscan2
- CES2 | chr16:66935513 C>G | 5'Flank (SNP) | VAF 52/247 reads (21%) | catalogued as COSV57696870; called by muse, mutect2, varscan2
- PAK3 | c.277-1618G>C | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948576 T>C | 3'Flank (SNP) | VAF 41/115 reads (36%) | catalogued as rs782164882, COSV99987349; called by muse, mutect2, varscan2
- TTN | c.10360+4193T>C | Intron (SNP) | VAF 26/46 reads (57%) | catalogued as rs566616408, COSV60060157; called by muse, mutect2, varscan2
